CCDI case PBBSUL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/695901fd-606c-4613-811a-1b6ebf855454

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ganglioneuroma: ICD-O-3 morphology code: 9490/0; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 10.1 years (3,677 days).

Biospecimens (3 samples)
- Sample 0DG0G7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGDW0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGDWG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
